Somatic mutation profile of tumor specimen TCGA-A6-2683-01A (aliquot TCGA-A6-2683-01A-01D-1953-10) from TCGA case TCGA-A6-2683, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.1 years (20,871 days).
Specimen TCGA-A6-2683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a5c703e-c07b-43e4-a96b-0fbb366b4bdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2683-10A (Blood Derived Normal), aliquot TCGA-A6-2683-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68e1e3ff-36f0-4b88-87b4-6b854d9bf4e8

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 40/55 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFAP65 | c.921T>A p.F307L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55391840, COSV99838476; called by muse, mutect2, varscan2
- DIAPH3 | c.2581G>A p.G861R (on ENST00000400324 / NM_001042517.2; = p.G598R on NM_030932.3) | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347883; called by muse, mutect2
- ERGIC3 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54141087; called by muse, mutect2, varscan2
- FAM184A | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138363; called by muse, mutect2, varscan2
- GCN1 | c.4670C>T p.A1557V | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100325984; called by muse, mutect2, varscan2
- HSPA12A | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 52/248 reads (21%) | catalogued as COSV100979705, COSV100979949; called by muse, mutect2, varscan2
- IRAK1 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100318508; called by muse, mutect2, varscan2
- ISLR2 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.28); catalogued as COSV62303730; called by muse, mutect2, varscan2
- KCNH2 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV100061078; called by muse, mutect2, varscan2
- KDM7A | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 112/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1458980046, COSV50091156; called by muse, varscan2
- KNDC1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs754738599, COSV100466244; called by muse, varscan2
- KRT81 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as rs998726616, COSV100577026; called by muse, mutect2, varscan2
- LIG1 | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs747656528, COSV54396073; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 432/671 reads (64%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LTK | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.183); catalogued as rs754293000, COSV99541178; called by mutect2, varscan2
- MYT1 | c.2704G>A p.G902S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752600921, COSV60500921; called by muse, mutect2, varscan2
- PARP3 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs754198499, COSV99027994; called by muse, mutect2, varscan2
- PC | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs776465359, COSV100852342; called by muse, varscan2
- PCDHA8 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as rs782580543, COSV100970092; called by muse, mutect2, varscan2
- PCDHA9 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV65324208, COSV65330053; called by mutect2, varscan2
- POTEH | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100625239; called by muse, mutect2, varscan2
- RALGDS | c.1518-1G>C p.X506_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100924379, COSV100924563; called by muse, mutect2, varscan2
- RGS21 | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV101314090; called by muse, mutect2, varscan2
- SCRIB | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs774556427, COSV100254146; called by muse, mutect2, varscan2
- SHROOM2 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as rs751441325, COSV101099045; called by mutect2, varscan2
- SLC6A3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs138948519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA20 | c.527C>T p.P176L (on ENST00000356488 / NM_001258372.1; = p.P192L on NM_022827.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136715; called by muse, mutect2, varscan2
- SPTA1 | c.3691G>T p.D1231Y | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63751780; called by muse, mutect2, varscan2
- ADAM22 | c.1560A>T p.S520= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV99718309; called by muse, mutect2, varscan2
- ATP13A3 | c.1944C>T p.D648= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as rs751347300, COSV99757644; called by muse, mutect2, varscan2
- CHST9 | c.1227C>T p.V409= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs371234835; called by muse, mutect2, varscan2
- FAAP100 | c.1443G>A p.K481= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs1317682366, COSV100585593; called by muse, mutect2, varscan2
- HTT | c.2214T>C p.P738= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100751255; called by muse, mutect2, varscan2
- PLEKHF1 | c.273G>A p.P91= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs768444045, COSV71409988; called by muse, mutect2, varscan2
- PRTN3 | c.333C>T p.D111= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99311654; called by muse, mutect2, varscan2
- SLC4A11 | c.1425C>T p.A475= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV101196128; called by muse, mutect2
- SPSB4 | c.528G>A p.S176= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1275502067, COSV100141752; called by muse, mutect2, varscan2
